Somatic mutation profile of tumor specimen C3L-02553-01 (aliquot CPT0161790006) from CPTAC case C3L-02553, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.3 years (20,920 days).
Specimen C3L-02553-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e4dfea4-1e82-475a-ba1d-7b5dedfbf2ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02553-31 (Blood Derived Normal), aliquot CPT0162560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c3dbbc-5fd8-4321-b19f-83569ffeaaba

The open-access MAF lists 108 somatic variants for this specimen: 75 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Frame Shift Del 9, Intron 5, 5'UTR 4, Splice Site 3, In Frame Del 2, 3'UTR 2, Frame Shift Ins 2, Nonstop Mutation 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 199/402 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28940297, CM045626, CM093523, CM951295, COSV56546736, COSV56559264, COSV56561769, COSV56569109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDOB | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 176/489 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs778058461, COSV66398673; called by muse, mutect2, varscan2
- ANGPT4 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.136); catalogued as COSV101124601; called by muse, mutect2, varscan2
- ANKRD44 | c.2647G>C p.G883R | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99984075; called by muse, mutect2, varscan2
- AXDND1 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1243773375; called by muse, mutect2, varscan2
- BCAS4 | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.505); catalogued as rs1352870774; called by muse, mutect2, varscan2
- COL12A1 | c.8567C>T p.P2856L | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs574147225, COSV59392497; called by muse, mutect2, varscan2
- ESR1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV99065446; called by muse, mutect2, varscan2
- NPAS4 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV60650595; called by muse, mutect2, varscan2
- PBX3 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as rs747120199; called by muse, mutect2
- RPE65 | c.1417G>C p.V473L | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs148859816, COSV99253585; called by muse, mutect2, varscan2
- SEMA6D | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768595343, COSV60381098; called by muse, mutect2, varscan2
- ZC3H6 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs545433319, COSV59666497; called by muse, varscan2
- A2M | c.2968C>G p.L990V | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA8 | c.1500A>G p.K500= | Splice Region (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ADAT2 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHDC1 | c.1197del p.G400Dfs*52 | Frame Shift Del (DEL) | VAF 93/273 reads (34%) | called by mutect2, pindel, varscan2
- ALG1 | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 150/524 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARF6 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARF6 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ARMC8 | c.375_376del p.L126Pfs*32 (on ENST00000469044 / NM_001363941.2; = p.L112Pfs*32 on NM_014154.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/220 reads (37%) | called by mutect2, pindel, varscan2
- ASAP3 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C14orf119 | c.404_408delinsAC p.A135_T136delinsD | In Frame Del (DEL) | VAF 7/78 reads (9%) | called by pindel, varscan2*
- CASP4 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 193/635 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CCDC178 | c.1177-2del p.X393_splice | Splice Site (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- CFAP57 | c.3032del p.F1011Sfs*10 (on ENST00000372492 / NM_001378189.1; = p.F1044Sfs*10 on NM_001195831.3) | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4754A>C p.*1585Sext*20 | Nonstop Mutation (SNP) | VAF 43/127 reads (34%) | called by muse, mutect2, varscan2
- CLASP1 | c.2830C>G p.L944V | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD1 | c.5920A>G p.T1974A (on ENST00000520002; = p.T1973A on NM_033225.6) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DDX60 | c.2545del p.E849Sfs*7 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | called by mutect2, pindel, varscan2
- EDEM2 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELP5 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM13C | c.423A>C p.E141D | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAT4 | c.14291_14292del p.H4764Rfs*3 | Frame Shift Del (DEL) | VAF 62/197 reads (31%) | called by mutect2, pindel, varscan2
- FBN3 | c.3127_3142del p.T1043Rfs*18 | Frame Shift Del (DEL) | VAF 32/173 reads (18%) | called by mutect2, pindel
- FES | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSR | c.481A>C p.N161H | Missense Mutation (SNP) | VAF 138/486 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF2I | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 140/552 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HNRNPA3 | c.366T>A p.H122Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- IGF2R | c.3887-2A>G p.X1296_splice | Splice Site (SNP) | VAF 174/589 reads (30%) | called by muse, mutect2, varscan2
- KAT6B | c.6003G>T p.M2001I | Missense Mutation (SNP) | VAF 156/465 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KATNA1 | c.1451G>T p.W484L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDRBS2 | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | called by mutect2, varscan2
- KIF16B | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF21B | c.2100_2101del p.K702Gfs*9 | Frame Shift Del (DEL) | VAF 134/459 reads (29%) | called by mutect2, pindel, varscan2
- KLHDC1 | c.308_314del p.T103Mfs*32 | Frame Shift Del (DEL) | VAF 47/177 reads (27%) | called by mutect2, pindel, varscan2
- KRT34 | c.1198A>C p.S400R | Missense Mutation (SNP) | VAF 118/340 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LIMD2 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK2 | c.1941+2T>A p.X647_splice | Splice Site (SNP) | VAF 91/279 reads (33%) | called by muse, mutect2, varscan2
- MAGED1 | c.1969dup p.R657Kfs*5 | Frame Shift Ins (INS) | VAF 17/32 reads (53%) | called by mutect2, pindel, varscan2
- MBOAT1 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MCUB | c.402dup p.K135* | Frame Shift Ins (INS) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- METTL7B | c.404A>C p.D135A | Missense Mutation (SNP) | VAF 163/460 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MEX3C | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MLXIPL | c.1838T>A p.L613Q | Missense Mutation (SNP) | VAF 429/822 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MYO7A | c.2180T>C p.F727S | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSUN7 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NTN5 | c.621C>G p.H207Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- NUDT13 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 180/606 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- OR2J2 | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- OR4Q2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PBRM1 | c.4180_4186del p.R1394* (on ENST00000296302 / NM_001366071.2; = p.R1342* on NM_018313.5) | Frame Shift Del (DEL) | VAF 181/408 reads (44%) | called by mutect2, pindel, varscan2
- POLRMT | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RAB11FIP1 | c.3014T>C p.V1005A | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAPGEF2 | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF6 | c.1855C>G p.L619V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RASA4 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); called by mutect2, varscan2
- RB1 | c.1948T>A p.F650I | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUSC1 | c.165_167del p.S56del | In Frame Del (DEL) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- STIM1 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TANGO6 | c.2483G>A p.S828N | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD9 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 151/533 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TLN2 | c.4291G>A p.A1431T | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TMEM186 | c.274T>G p.L92V | Missense Mutation (SNP) | VAF 117/354 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WASF2 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALG1 | c.162G>C p.L54= | Silent (SNP) | VAF 151/522 reads (29%) | called by muse, mutect2, varscan2
- ARRB1 | c.399C>T p.P133= | Silent (SNP) | VAF 95/313 reads (30%) | catalogued as rs772201191; called by muse, mutect2, varscan2
- CHD7 | c.7503C>A p.S2501= | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2
- COL6A2 | c.939A>G p.G313= | Silent (SNP) | VAF 209/632 reads (33%) | called by muse, mutect2, varscan2
- DMGDH | c.246A>G p.S82= | Silent (SNP) | VAF 168/539 reads (31%) | called by muse, mutect2, varscan2
- FAM186A | c.6237G>A p.L2079= | Silent (SNP) | VAF 120/342 reads (35%) | catalogued as rs1276446593; called by muse, mutect2, varscan2
- FBN2 | c.8058C>T p.F2686= | Silent (SNP) | VAF 168/492 reads (34%) | catalogued as rs150734807, COSV52489741; called by muse, mutect2, varscan2
- GAL3ST4 | c.615C>T p.Y205= | Silent (SNP) | VAF 125/498 reads (25%) | catalogued as rs374453623; called by muse, mutect2, varscan2
- HSP90AA1 | c.498A>G p.A166= | Silent (SNP) | VAF 114/331 reads (34%) | called by muse, mutect2, varscan2
- IL17RA | c.1413C>T p.H471= | Silent (SNP) | VAF 177/483 reads (37%) | called by muse, mutect2, varscan2
- L3HYPDH | c.960T>C p.F320= | Silent (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- MUC17 | c.4671T>G p.T1557= | Silent (SNP) | VAF 131/273 reads (48%) | called by muse, mutect2, varscan2
- MUC17 | c.10191A>T p.G3397= | Silent (SNP) | VAF 120/252 reads (48%) | called by muse, mutect2, varscan2
- OR4Q2 | c.753C>G p.P251= | Silent (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- RNFT2 | c.306C>T p.G102= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- SLC45A4 | c.744G>T p.L248= (on ENST00000517878 / NM_001286646.2; = p.L197= on NM_001080431.2) | Silent (SNP) | VAF 101/313 reads (32%) | called by muse, mutect2, varscan2
- SPTA1 | c.1539C>G p.A513= | Silent (SNP) | VAF 206/616 reads (33%) | called by muse, varscan2
- TDRD9 | c.492G>A p.Q164= | Silent (SNP) | VAF 151/527 reads (29%) | called by muse, mutect2, varscan2
- UBTFL1 | c.750C>A p.R250= | Silent (SNP) | VAF 214/729 reads (29%) | called by muse, mutect2, varscan2
- VPS13B | c.6960G>A p.G2320= | Silent (SNP) | VAF 48/212 reads (23%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976372 G>A | 3'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs111332561; called by muse, varscan2
- ANK2 | c.85-57053G>A | Intron (SNP) | VAF 81/292 reads (28%) | called by muse, mutect2, varscan2
- BRD1 | c.2360-271_2360-261delinsA | Intron (DEL) | VAF 26/197 reads (13%) | called by pindel, varscan2*
- CD8A | c.*279T>C | 3'UTR (SNP) | VAF 180/546 reads (33%) | called by muse, mutect2, varscan2
- CHD8 | c.6772-277A>G | Intron (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.1del | 5'UTR (DEL) | VAF 24/54 reads (44%) | called by mutect2, varscan2
- ISCU | c.-5G>A | 5'UTR (SNP) | VAF 34/115 reads (30%) | catalogued as rs1490751535; called by muse, mutect2, varscan2
- LIN28A | c.-26C>A | 5'UTR (SNP) | VAF 118/401 reads (29%) | catalogued as rs763514579; called by muse, mutect2, varscan2
- LRRC37BP1 | n.1122G>A | RNA (SNP) | VAF 156/550 reads (28%) | called by muse, mutect2, varscan2
- LSM1 | c.46+12_46+13dup | Intron (INS) | VAF 41/157 reads (26%) | called by mutect2, pindel, varscan2
- MMAB | c.*2178G>T | 3'UTR (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- SPG11 | c.3520+1856_3520+1861del | Intron (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ST6GALNAC5 | c.-42G>A | 5'UTR (SNP) | VAF 155/464 reads (33%) | called by muse, mutect2, varscan2
